Somatic mutation profile of tumor specimen TARGET-20-PASFEW-09A (aliquot TARGET-20-PASFEW-09A-01D) from TARGET case TARGET-20-PASFEW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (428 days).
Specimen TARGET-20-PASFEW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1efed43-be3f-41aa-a85b-a248504bbbd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASFEW-14A (Bone Marrow Normal), aliquot TARGET-20-PASFEW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49820bc1-7500-475d-8c67-6d8a25f825f6

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX30 | c.520C>T p.R174* (on ENST00000445061 / NM_138615.3; = p.R135* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as rs1327652941, COSV62393949; called by muse, mutect2, varscan2
- MINDY4 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs757043983, COSV54672348; called by muse, mutect2, varscan2
- TCP11 | c.994G>A p.V332I (on ENST00000512012; = p.V270I on NM_018679.5) | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765786893, COSV55131752, COSV55133326; called by muse, mutect2, varscan2
- SYP | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, mutect2
- PLG | c.585C>A p.G195= | Silent (SNP) | VAF 20/186 reads (11%) | catalogued as COSV51982235; called by muse, mutect2, varscan2
